Somatic mutation profile of tumor specimen TCGA-60-2695-01A (aliquot TCGA-60-2695-01A-01W-0877-08) from TCGA case TCGA-60-2695, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.5 years (27,211 days).
Specimen TCGA-60-2695-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c50a6930-fa04-4ee5-8ae8-db0d6953d97f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2695-11A (Solid Tissue Normal), aliquot TCGA-60-2695-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/254107fc-c864-49cb-b41a-b5b2b1302b2f

The open-access MAF lists 192 somatic variants for this specimen: 149 protein-altering or splice-affecting, 41 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 41, Nonsense Mutation 10, Frame Shift Del 4, Frame Shift Ins 2, Translation Start Site 2, Splice Site 2, Intron 1, RNA 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 69/364 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-2A>G p.X225_splice | Splice Site (SNP) | VAF 243/277 reads (88%) | hotspot (GDC flag); catalogued as rs1555525585, CS109519, COSV52669186, COSV52682653, COSV52687702; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB7 | c.988G>C p.G330R (on ENST00000373394 / NM_001271696.3; = p.G331R on NM_004299.6) | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV53721135, COSV99504627; called by muse, mutect2, varscan2
- ABCG2 | c.1915A>G p.I639V | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV99419732; called by muse, mutect2, varscan2
- AC136428.1 | c.27C>A p.F9L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); catalogued as COSV101434978; called by mutect2, varscan2
- ADAMTS3 | c.2162G>T p.R721I | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54393276, COSV99711689; called by muse, mutect2, varscan2
- ADGRA3 | c.1729C>G p.R577G | Missense Mutation (SNP) | VAF 175/440 reads (40%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.982); catalogued as COSV99293574; called by muse, mutect2, varscan2
- ADGRE3 | c.1174C>A p.H392N | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV99506485; called by muse, mutect2, varscan2
- ARHGEF11 | c.2956G>T p.V986L | Missense Mutation (SNP) | VAF 68/329 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as COSV100168813; called by muse, mutect2, varscan2
- ARHGEF6 | c.2245C>A p.L749I | Missense Mutation (SNP) | VAF 44/922 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV99166586; called by muse, mutect2
- ASTN1 | c.1973G>T p.G658V | Missense Mutation (SNP) | VAF 150/307 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56067429, COSV99922544; called by muse, mutect2, varscan2
- ATP1B1 | c.897T>G p.I299M | Missense Mutation (SNP) | VAF 60/294 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.442); catalogued as COSV100891116; called by muse, mutect2, varscan2
- BBX | c.2487A>C p.K829N (on ENST00000325805 / NM_001142568.3; = p.K799N on NM_020235.7) | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100362043; called by muse, mutect2, varscan2
- BCLAF1 | c.779A>T p.Q260L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.306); catalogued as COSV62144391; called by muse, mutect2, varscan2
- BEST2 | c.949-2A>T p.X317_splice | Splice Site (SNP) | VAF 141/428 reads (33%) | catalogued as COSV99244571; called by mutect2, varscan2
- BMX | c.77A>T p.Y26F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as COSV100564579; called by muse, mutect2, varscan2
- C2orf16 | c.3724T>A p.L1242I | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.236); catalogued as COSV100820898; called by muse, mutect2, varscan2
- CACNA1S | c.1730del p.G577Afs*35 | Frame Shift Del (DEL) | VAF 77/447 reads (17%) | catalogued as COSV62935588; called by mutect2, pindel, varscan2
- CALCR | c.220C>A p.R74S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100810718; called by muse, mutect2, varscan2
- CALM1 | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as COSV100811163; called by muse, mutect2, varscan2
- CALN1 | c.41G>T p.G14V (on ENST00000329008 / NM_001017440.3; = p.G56V on NM_031468.4) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100208327; called by muse, mutect2, varscan2
- CALN1 | c.40G>T p.G14W (on ENST00000329008 / NM_001017440.3; = p.G56W on NM_031468.4) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100205157, COSV61149726; called by muse, mutect2, varscan2
- CCDC150 | c.2685A>T p.Q895H | Missense Mutation (SNP) | VAF 104/268 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99777192; called by muse, mutect2, varscan2
- CCDC81 | c.1429A>T p.M477L (on ENST00000445632 / NM_001156474.2; = p.M387L on NM_021827.4) | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV99564643; called by muse, mutect2, varscan2
- CMBL | c.23G>T p.C8F | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV99687170; called by muse, varscan2
- CSMD1 | c.10168T>G p.F3390V (on ENST00000520002; = p.F3389V on NM_033225.6) | Missense Mutation (SNP) | VAF 90/118 reads (76%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV100151532; called by muse, mutect2, varscan2
- CYBB | c.117C>G p.F39L | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV101059796, COSV66084945, COSV66085645; called by muse, mutect2, varscan2
- CYLC2 | c.696A>G p.I232M | Missense Mutation (SNP) | VAF 97/155 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100872514; called by muse, mutect2, varscan2
- CYP11B1 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1554653200, COSV52829219; ClinVar: uncertain significance; called by muse, mutect2
- CYP1A2 | c.1376T>G p.I459S | Missense Mutation (SNP) | VAF 104/190 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100673919; called by muse, mutect2, varscan2
- CYP2C19 | c.613A>T p.I205F | Missense Mutation (SNP) | VAF 87/256 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100990584; called by muse, mutect2, varscan2
- DAPK3 | c.426G>C p.P142= | Splice Region (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100009811; called by muse, mutect2, varscan2
- DBNDD1 | c.76C>G p.P26A (on ENST00000002501 / NM_001042610.3; = p.P46A on NM_024043.3) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.098); catalogued as COSV99136540; called by mutect2, varscan2
- DCAF12L1 | c.1064C>A p.S355* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV100948387; called by muse, mutect2, varscan2
- DDI1 | c.132G>C p.E44D | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.046); catalogued as COSV100160153, COSV56388047; called by muse, mutect2, varscan2
- DLC1 | c.1096G>C p.D366H | Missense Mutation (SNP) | VAF 184/210 reads (88%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs779862909, COSV99364487; called by muse, mutect2, varscan2
- DLG3 | c.586C>A p.H196N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99529876; called by muse, mutect2, varscan2
- DLK1 | c.619C>A p.R207S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.946); catalogued as COSV100375349, COSV57991368; called by muse, mutect2, varscan2
- DNAH7 | c.3919A>G p.T1307A | Missense Mutation (SNP) | VAF 79/218 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100416439; called by muse, mutect2, varscan2
- DSG3 | c.1108G>T p.V370F | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV99934512; called by muse, mutect2, varscan2
- ECRG4 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99430445; called by muse, mutect2, varscan2
- EGFLAM | c.1121G>A p.G374D | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59294519; called by muse, varscan2
- EIF2AK4 | c.4567T>C p.F1523L | Missense Mutation (SNP) | VAF 35/51 reads (69%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV99775108; called by muse, mutect2, varscan2
- FAM133A | c.52A>G p.R18G | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100220536; called by muse, mutect2, varscan2
- FMR1 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 73/223 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs1272102686, COSV54426435; called by muse, mutect2, varscan2
- GJB1 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV100661289; called by muse, mutect2, varscan2
- GLIPR1 | c.481G>C p.G161R | Missense Mutation (SNP) | VAF 76/140 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV99875798; called by muse, mutect2, varscan2
- GLT1D1 | c.682G>T p.G228* (on ENST00000442111 / NM_001366889.1; = p.G148* on NM_144669.3) | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV55880686, COSV55885260; called by muse, varscan2
- GNB4 | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 65/250 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs1222953811, COSV104372412, COSV99224408; called by muse, mutect2, varscan2
- GPR158 | c.2967C>G p.D989E | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV100894034; called by muse, mutect2, varscan2
- GZMA | c.220A>G p.K74E | Missense Mutation (SNP) | VAF 102/127 reads (80%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV99956620; called by muse, mutect2, varscan2
- HNRNPA1L2 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.708); catalogued as COSV100676523; called by muse, mutect2, varscan2
- HSPA8 | c.1616A>T p.K539M | Missense Mutation (SNP) | VAF 107/240 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV57085441, COSV99914529; called by muse, mutect2, varscan2
- HTR1E | c.751G>T p.D251Y | Missense Mutation (SNP) | VAF 26/486 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100541202, COSV59508949; called by muse, mutect2
- HUWE1 | c.347T>C p.I116T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs1347758273, COSV99473425; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.309C>A p.S103R | Missense Mutation (SNP) | VAF 188/793 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.219); catalogued as rs1272197745; called by muse, mutect2, varscan2
- IGSF10 | c.3151A>C p.T1051P | Missense Mutation (SNP) | VAF 173/468 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs922558965, COSV56790845, COSV99185153; called by mutect2, varscan2
- KCNH1 | c.486G>T p.R162S | Missense Mutation (SNP) | VAF 129/221 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.439); catalogued as COSV99660416; called by muse, mutect2, varscan2
- KCNH7 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.829); catalogued as COSV100036981; called by muse, mutect2, varscan2
- KIF21A | c.4130G>A p.G1377E (on ENST00000361418 / NM_001378440.1; = p.G1364E on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100735554; called by muse, mutect2, varscan2
- KLHL13 | c.1369A>T p.T457S | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.104); catalogued as COSV53249143, COSV99452186; called by muse, mutect2
- KLHL32 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 44/158 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV100987428; called by muse, mutect2, varscan2
- KRTAP13-2 | c.335A>G p.Y112C | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.133); catalogued as COSV101299659; called by muse, mutect2, varscan2
- LRRFIP2 | c.356C>G p.S119* | Nonsense Mutation (SNP) | VAF 8/112 reads (7%) | catalogued as COSV100368604; called by muse, mutect2
- LTBP2 | c.2101G>T p.V701L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100000735, COSV56205878; called by muse, mutect2
- MED12 | c.4223C>A p.P1408H | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.428); catalogued as COSV100379161; called by muse, mutect2, varscan2
- MED12L | c.4157T>C p.I1386T | Missense Mutation (SNP) | VAF 73/158 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs1315050599, COSV99854053; called by muse, mutect2, varscan2
- MPP6 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV99757712; called by muse, mutect2, varscan2
- MPST | c.769G>A p.V257M (on ENST00000341116 / NM_001369904.2; = p.V277M on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs1227456722; called by muse, mutect2
- MTMR9 | c.1612G>T p.E538* | Nonsense Mutation (SNP) | VAF 99/119 reads (83%) | catalogued as COSV99644455; called by muse, mutect2, varscan2
- MTUS2 | c.790del p.A264Hfs*21 | Frame Shift Del (DEL) | VAF 59/106 reads (56%) | catalogued as COSV101462155, COSV101462372; called by mutect2, pindel, varscan2
- MYO5A | c.4780G>C p.D1594H | Missense Mutation (SNP) | VAF 56/576 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62560735; called by muse, mutect2
- NAALAD2 | c.13A>G p.R5G | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1004399621, COSV100428659; called by muse, varscan2
- NDUFB4 | c.155A>G p.N52S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99481912; called by muse, mutect2, varscan2
- NLRC5 | c.4151T>G p.L1384R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99347840; called by muse, mutect2, varscan2
- NLRP12 | c.3089G>T p.R1030L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV100145570; called by muse, mutect2, varscan2
- NOP58 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV99970745; called by muse, mutect2, varscan2
- NTPCR | c.553G>T p.V185L | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100786730, COSV64052914; called by muse, mutect2, varscan2
- OR4C3 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 49/406 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs752508677, COSV100167730; called by muse, varscan2
- OR4Q3 | c.224T>A p.L75H | Missense Mutation (SNP) | VAF 131/332 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100057240; called by mutect2, varscan2
- OR8D1 | c.72G>C p.Q24H | Missense Mutation (SNP) | VAF 117/351 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100766665, COSV100766680; called by muse, mutect2, varscan2
- ORC5 | c.1015A>T p.N339Y | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.271); catalogued as COSV99857221; called by muse, mutect2, varscan2
- OTOGL | c.1798G>T p.E600* (on ENST00000547103; = p.E591* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 22/97 reads (23%) | catalogued as COSV101509452; called by muse, mutect2, varscan2
- OTOGL | c.4007C>A p.T1336K (on ENST00000547103; = p.T1327K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV101509453; called by muse, mutect2, varscan2
- PATJ | c.2810del p.P937Rfs*9 | Frame Shift Del (DEL) | VAF 90/359 reads (25%) | catalogued as rs1257256888; called by mutect2, pindel, varscan2
- PCDHGA4 | c.2146G>T p.D716Y | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV99542941; called by muse, mutect2, varscan2
- PCDHGA8 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV53949255; called by muse, mutect2, varscan2
- PCTP | c.422C>G p.P141R | Missense Mutation (SNP) | VAF 92/102 reads (90%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV99273860; called by muse, mutect2, varscan2
- PDCD1 | c.722G>A p.C241Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.75); catalogued as COSV100545497; called by mutect2, varscan2
- PIK3CG | c.1139C>G p.T380R | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.055); catalogued as COSV100783036, COSV63255830; called by muse, mutect2, varscan2
- PLOD2 | c.1837A>T p.M613L | Missense Mutation (SNP) | VAF 45/244 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as COSV99283065; called by muse, mutect2, varscan2
- POLQ | c.2198C>T p.P733L | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV99952601; called by muse, mutect2, varscan2
- PPP2R2C | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 123/247 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV100065909, COSV100067021; called by muse, mutect2, varscan2
- PSG9 | c.112A>C p.I38L | Missense Mutation (SNP) | VAF 17/506 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99392470; called by muse, mutect2
- PTPRD | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 148/573 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61932719; called by muse, mutect2, varscan2
- RBM10 | c.330G>T p.E110D | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV100238090; called by muse, mutect2, varscan2
- RIMS1 | c.3199A>G p.I1067V | Missense Mutation (SNP) | VAF 61/84 reads (73%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1218764769, COSV99328911; called by muse, mutect2, varscan2
- RPGR | c.1645G>T p.E549* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100140252, COSV58836251; called by muse, mutect2, varscan2
- RPL10L | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs779935712, COSV100022659; called by muse, mutect2, varscan2
- RYR1 | c.6701G>C p.R2234P | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100616462, COSV62112283; called by muse, mutect2, varscan2
- RYR2 | c.8891C>A p.A2964E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.451); catalogued as COSV100772041; called by muse, mutect2, varscan2
- SEC31A | c.3367T>A p.F1123I (on ENST00000355196 / NM_001318120.1; = p.F1084I on NM_016211.4) | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100022157; called by muse, mutect2, varscan2
- SEL1L3 | c.550A>G p.R184G | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99340839; called by muse, mutect2, varscan2
- SELP | c.1084G>C p.G362R | Missense Mutation (SNP) | VAF 87/464 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99740632; called by muse, mutect2, varscan2
- SERPINB4 | c.161G>T p.S54I | Missense Mutation (SNP) | VAF 110/454 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV100345870, COSV61985322; called by muse, mutect2, varscan2
- SHANK1 | c.2490A>T p.Q830H | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99521681; called by muse, mutect2, varscan2
- SLC30A1 | c.1402T>G p.S468A | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100879144; called by muse, mutect2, varscan2
- SLC4A5 | c.1636G>A p.A546T | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100697861; called by muse, mutect2, varscan2
- SLC7A7 | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 98/225 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99591537; called by muse, mutect2, varscan2
- SORCS1 | c.1732T>A p.W578R | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99548562; called by muse, mutect2, varscan2
- SPATA31D1 | c.3335G>T p.S1112I | Missense Mutation (SNP) | VAF 89/284 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.414); catalogued as COSV100782930; called by muse, mutect2, varscan2
- SULT1A2 | c.212A>G p.H71R | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs995826819, COSV100187286; called by muse, varscan2
- SVEP1 | c.9953G>T p.G3318V | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99929475; called by muse, mutect2, varscan2
- TAF1A | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 155/518 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV100601041; called by muse, mutect2, varscan2
- TBC1D4 | c.2816A>C p.H939P | Missense Mutation (SNP) | VAF 88/102 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100884718; called by muse, mutect2, varscan2
- TBC1D8B | c.2180G>T p.G727V | Missense Mutation (SNP) | VAF 13/330 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.343); catalogued as COSV99344816; called by muse, mutect2
- TBX5 | c.441T>A p.H147Q | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.39); PolyPhen benign (0.267); catalogued as COSV100091700; called by muse, mutect2, varscan2
- TCEAL6 | c.251C>A p.P84Q | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.406); catalogued as COSV101035892; called by muse, mutect2, varscan2
- TCHH | c.3467A>C p.E1156A | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV100915292; called by muse, mutect2, varscan2
- TENM2 | c.2878A>G p.T960A (on ENST00000518659 / NM_001122679.2; = p.T728A on NM_001080428.3) | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV101319198; called by mutect2, varscan2
- TEX55 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 110/184 reads (60%) | SIFT tolerated (0.49); PolyPhen benign (0.301); catalogued as COSV55211478, COSV99817680; called by muse, mutect2, varscan2
- TFCP2L1 | c.723G>T p.E241D | Missense Mutation (SNP) | VAF 106/266 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.651); catalogued as COSV99748507; called by muse, mutect2, varscan2
- THOC2 | c.4757A>G p.H1586R | Missense Mutation (SNP) | VAF 104/236 reads (44%) | SIFT tolerated, low confidence (0.41); PolyPhen probably damaging (0.95); catalogued as COSV99833823; called by muse, mutect2, varscan2
- THOC2 | c.29C>A p.A10E | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV55547289, COSV99833828; called by muse, mutect2, varscan2
- TOP3A | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | catalogued as rs1163645463, COSV58179529; called by muse, mutect2, varscan2
- TPTE | c.1031G>C p.R344T (on ENST00000618007 / NM_199261.4; = p.R326T on NM_199259.4) | Missense Mutation (SNP) | VAF 64/346 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456490474; called by muse, mutect2, varscan2
- TTC37 | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 70/81 reads (86%) | catalogued as COSV100706764; called by muse, mutect2, varscan2
- TTLL4 | c.26A>G p.Y9C | Missense Mutation (SNP) | VAF 99/214 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99293583; called by muse, mutect2, varscan2
- UGGT1 | c.1589G>T p.G530V | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99390966; called by muse, mutect2, varscan2
- USP45 | c.47G>C p.R16T | Missense Mutation (SNP) | VAF 28/467 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57329337, COSV57330668, COSV57330843; called by muse, mutect2
- VCX | c.38A>T p.K13M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.452); catalogued as COSV100406345; called by muse, varscan2
- VPS35L | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as COSV51981768; called by muse, varscan2
- WIPI2 | c.235G>C p.V79L | Missense Mutation (SNP) | VAF 20/221 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99993506; called by muse, mutect2
- WNT16 | c.397C>A p.H133N (on ENST00000222462 / NM_057168.2; = p.H123N on NM_016087.2) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99743304; called by muse, mutect2, varscan2
- XIRP2 | c.2041G>C p.V681L (on ENST00000628543; = p.V856L on NM_152381.6) | Missense Mutation (SNP) | VAF 79/214 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99745546; called by muse, mutect2, varscan2
- ZCCHC12 | c.554G>T p.S185I | Missense Mutation (SNP) | VAF 157/303 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); catalogued as COSV100038619; called by muse, mutect2, varscan2
- ZGRF1 | c.3692A>T p.N1231I | Missense Mutation (SNP) | VAF 108/254 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV100481204; called by muse, varscan2
- ZIM2 | c.796T>A p.L266M | Missense Mutation (SNP) | VAF 147/248 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV99689809; called by muse, mutect2, varscan2
- ZNF23 | c.1165G>T p.E389* | Nonsense Mutation (SNP) | VAF 43/131 reads (33%) | catalogued as COSV100612217; called by muse, mutect2, varscan2
- ZNF783 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100954275; called by mutect2, varscan2
- ZNF804A | c.2105G>T p.G702V | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as COSV100169198; called by muse, mutect2, varscan2
- BAZ2B | c.4188dup p.V1397Cfs*8 | Frame Shift Ins (INS) | VAF 32/99 reads (32%) | called by mutect2, pindel, varscan2
- CKAP5 | c.1885C>A p.L629I | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.039); called by muse, mutect2
- INTS12 | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 27/859 reads (3%) | called by muse, mutect2
- OR4D2 | c.175dup p.M59Nfs*30 | Frame Shift Ins (INS) | VAF 372/534 reads (70%) | called by mutect2, varscan2
- RASA3 | c.1150A>G p.M384V | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2
- SLCO1B3 | c.1266del p.Q422Hfs*7 | Frame Shift Del (DEL) | VAF 30/136 reads (22%) | called by mutect2, pindel, varscan2
- SLX4 | c.495_497del p.Q166del | In Frame Del (DEL) | VAF 36/100 reads (36%) | called by mutect2, varscan2
- ZNF26 | c.1497A>T p.E499D | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AC004922.1 | c.951G>A p.T317= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as rs752395773, COSV53555559; called by muse, mutect2, varscan2
- ACTC1 | c.594T>C p.R198= | Silent (SNP) | VAF 92/224 reads (41%) | catalogued as COSV99292045; called by muse, mutect2, varscan2
- CACNA1B | c.4536C>A p.S1512= | Silent (SNP) | VAF 35/122 reads (29%) | catalogued as COSV99498712; called by muse, mutect2, varscan2
- CASP2 | c.567G>A p.Q189= | Silent (SNP) | VAF 84/203 reads (41%) | catalogued as COSV100131177; called by muse, mutect2, varscan2
- CCNL2 | c.1530G>T p.R510= | Silent (SNP) | VAF 47/87 reads (54%) | catalogued as COSV101275704; called by muse, varscan2
- CDH7 | c.357G>T p.T119= | Silent (SNP) | VAF 61/104 reads (59%) | catalogued as rs201657602, COSV59881319, COSV59883575; called by muse, mutect2, varscan2
- CHIA | c.1236G>A p.G412= (on ENST00000343320; = p.G304= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 58/109 reads (53%) | catalogued as COSV100588578; called by muse, mutect2, varscan2
- CLPTM1 | c.336C>T p.H112= | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as rs757264276, COSV61613307; called by muse, mutect2, varscan2
- DLAT | c.1503A>C p.T501= | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- GAK | c.3411G>T p.P1137= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as COSV58504034; called by muse, mutect2, varscan2
- GAL3ST1 | c.567C>T p.A189= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV100143178; called by muse, mutect2, varscan2
- GLIS1 | c.204G>A p.L68= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as COSV100390480; called by muse, mutect2, varscan2
- GTF2IRD2B | c.2487C>G p.L829= | Silent (SNP) | VAF 56/243 reads (23%) | called by muse, mutect2, varscan2
- HHIPL2 | c.330G>A p.S110= | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as rs775190458, COSV100596998; called by muse, mutect2, varscan2
- IMPA2 | c.474G>T p.R158= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV99302689; called by muse, varscan2
- ITFG2 | c.27C>A p.R9= | Silent (SNP) | VAF 42/388 reads (11%) | called by muse, mutect2, varscan2
- KCNH7 | c.222C>T p.T74= | Silent (SNP) | VAF 38/74 reads (51%) | catalogued as COSV100036986; called by muse, mutect2, varscan2
- MAGEL2 | c.2511C>T p.V837= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV58568010; called by muse, mutect2, varscan2
- MUC13 | c.1470G>A p.T490= | Silent (SNP) | VAF 53/210 reads (25%) | catalogued as rs776470626, COSV100222427; called by muse, mutect2, varscan2
- MYO5C | c.4383A>G p.E1461= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as COSV99955116; called by muse, mutect2, varscan2
- NBAS | c.4080G>C p.L1360= | Silent (SNP) | VAF 190/621 reads (31%) | catalogued as rs144401114; called by muse, mutect2, varscan2
- NPFFR1 | c.342C>G p.A114= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV99524927; called by muse, mutect2, varscan2
- OR10G4 | c.231C>A p.P77= | Silent (SNP) | VAF 47/270 reads (17%) | catalogued as COSV100304915; called by muse, varscan2
- OR52J3 | c.129C>T p.G43= | Silent (SNP) | VAF 37/103 reads (36%) | catalogued as COSV100984907, COSV66746722; called by muse, mutect2, varscan2
- PCDHB6 | c.186C>T p.G62= | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as rs1554277416, COSV50720671; called by muse, mutect2, varscan2
- PCDHGA2 | c.1947C>T p.H649= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as rs769573354, COSV53965443; called by muse, mutect2, varscan2
- PDHX | c.951A>G p.Q317= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as COSV99927775; called by muse, mutect2, varscan2
- RET | c.3309C>A p.P1103= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV100394158; called by muse, varscan2
- RFFL | c.768G>C p.R256= | Silent (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2
- RLF | c.3966C>T p.T1322= | Silent (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- SCML1 | c.357C>A p.L119= (on ENST00000380041 / NM_001037540.3; = p.L92= on NM_006746.6) | Silent (SNP) | VAF 41/186 reads (22%) | catalogued as COSV101193962; called by muse, mutect2, varscan2
- SH3BP4 | c.672C>T p.N224= | Silent (SNP) | VAF 68/185 reads (37%) | catalogued as rs1189062417, COSV60642302; called by muse, mutect2, varscan2
- SLC2A6 | c.168G>T p.L56= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV100902765; called by muse, mutect2, varscan2
- SLC5A4 | c.237C>A p.I79= | Silent (SNP) | VAF 62/415 reads (15%) | catalogued as rs201777124, COSV99832057; called by muse, mutect2, varscan2
- SMS | c.378C>G p.T126= | Silent (SNP) | VAF 39/119 reads (33%) | catalogued as COSV101048196, COSV65113759; called by muse, mutect2, varscan2
- TGFBR2 | c.774C>G p.V258= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV99847670; called by muse, mutect2, varscan2
- TGFBR2 | c.879C>T p.I293= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as COSV99847673; called by muse, mutect2, varscan2
- TRBV6-1 | c.120G>T p.L40= | Silent (SNP) | VAF 144/360 reads (40%) | called by muse, mutect2, varscan2
- TTLL4 | c.1755T>A p.P585= | Silent (SNP) | VAF 34/307 reads (11%) | called by muse, mutect2, varscan2
- UNC5D | c.1860C>A p.I620= | Silent (SNP) | VAF 352/433 reads (81%) | catalogued as COSV54773312, COSV99777437; called by muse, mutect2, varscan2
- USP34 | c.225A>G p.Q75= | Silent (SNP) | VAF 166/325 reads (51%) | catalogued as rs751599888, COSV101277129; called by muse, mutect2, varscan2
- PHACTR4 | c.1816+638A>G | Intron (SNP) | VAF 226/407 reads (56%) | catalogued as COSV100868479; called by muse, mutect2, varscan2
- UBTFL2 | n.298C>A | RNA (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
